Gene-level copy-number profile of tumor specimen TCGA-ZG-A9LB-01A from TCGA case TCGA-ZG-A9LB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.4 years (26,447 days).
Specimen TCGA-ZG-A9LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.92e38059-d0c0-4604-935b-af4410305028.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9LB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/131a06ba-7065-43d9-a78d-85cb2e120101

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 340; copy number 2: 15,883; copy number 3: 26,506; copy number 4: 13,241; copy number 5: 2,050; copy number 6: 83; copy number 9: 288; copy number 10: 271; copy number 11: 951; copy number 13: 23; copy number 14: 178.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9LB-01A-11D-A41J-01): tumor purity 0.53, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,711 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,421,341–145,066,685, 1,702 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr19:53,431,984–53,580,269, 9 genes, copy number 14: TPM3P9, ZNF761, AC022137.3, ZNF813, TPM3P6, AC022137.1, AC011487.1, AC011487.3, ZNF331.

Autosomal genes at a single copy (total copy number 1): 340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
